Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A1MF, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A1MF-01A (Primary Tumor).

ICD-0.3
Carcinoma, squamous cell, NOS 8070/3
Site: Cervix, NOS C53.9 2/24/11 *lw*

Sent [REDACTED] 12/15

SURGICAL PATHOLOGY REPORT

Patient Name: [REDACTED]
Address: [REDACTED]
Gender: F
DOB: [REDACTED]
Service: Gynecology
Location: [REDACTED]
MRN: [REDACTED]
Hospital #: 1 [REDACTED]
Patient Type: [REDACTED]
Accession #: [REDACTED]
Taken: [REDACTED]
Received: [REDACTED]
Reported: [REDACTED]

Physician(s): [REDACTED] D.

DIAGNOSIS:

UTERUS, CERVIX, RADICAL HYSTERECTOMY
- INVASIVE, MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA KERATINIZING TYPE,
5.2 CM IN GREATEST DIMENSION
- TUMOR INVADERS TO A DEPTH OF 18 MM WHERE THE TOTAL WALL THICKNESS MEASURES 22 MM
- FOCAL LYMPHVASCULAR SPACE INVASION IS IDENTIFIED
- RESECTION MARGINS ARE FREE OF CARCINOMA

VAGINA, CUFF, MARGINS, RADICAL HYSTERECTOMY
- NO DYSPLASIA OR CARCINOMA IDENTIFIED

PARAMETRIAL SOFT TISSUE, RADICAL HYSTERECTOMY
- NO CARCINOMA IDENTIFIED

UTERUS, ENDOMETRIUM, RADICAL HYSTERECTOMY
- ENDOMETRIAL POLYP
- EARLY MENSTRUAL ENDOMETRIUM

UTERUS, MYOMETRIUM, RADICAL HYSTERECTOMY
- ADENOMYOSIS
- LEIOMYOMA, MICROSCOPIC

UTERUS, SEROSA, RADICAL HYSTERECTOMY
- SUBSEROUSAL ENDOSALPINGIOSIS

OVARY, LEFT, SALPINGO OOPHORECTOMY
- PARAOVARIAN ADHESIONS

FALLOPIAN TUBE, LEFT SALPINGO OOPHORECTOMY
- NO HISTOPATHOLOGIC ABNORMALITY

OVARY, RIGHT, SALPINGO OOPHORECTOMY
- NO HISTOPATHOLOGIC ABNORMALITY

FALLOPIAN TUBE, RIGHT, SALPINGO OOPHORECTOMY
- NO HISTOPATHOLOGIC ABNORMALITY

Source: NCI Genomic Data Commons file d9bc0f2d-543d-4241-a268-ad2968dccdb6 (TCGA-C5-A1MF.1FEEF445-9E69-4AAB-A336-C688BA807CDA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).